Somatic mutation profile of tumor specimen TCGA-XF-A9SH-01A (aliquot TCGA-XF-A9SH-01A-11D-A391-08) from TCGA case TCGA-XF-A9SH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 65.9 years (24,060 days).
Specimen TCGA-XF-A9SH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193c5cc8-c035-4f30-b85f-83a4fe993f38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9SH-10A (Blood Derived Normal), aliquot TCGA-XF-A9SH-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b138acdf-dea2-483d-a2e2-9df4b0fe599f

The open-access MAF lists 46 somatic variants for this specimen: 31 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Intron 1, 5'UTR 1, In Frame Del 1, Nonsense Mutation 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99523714; called by muse, mutect2, varscan2
- ARNT | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV100591363; called by muse, mutect2, varscan2
- CCDC90B | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99475425; called by muse, mutect2, varscan2
- CFH | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 4/101 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as COSV100661625; called by muse, mutect2
- COL6A6 | c.6584G>A p.R2195Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs544399652, COSV62018767; called by muse, mutect2, varscan2
- CYC1 | c.161C>G p.S54C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV100010602; called by muse, mutect2, varscan2
- CYTH2 | c.1160G>C p.R387T (on ENST00000427476; = p.R386T on NM_004228.7) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100287354; called by muse, mutect2, varscan2
- DIPK1C | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200796961, COSV100679717, COSV59725392; called by muse, varscan2
- GLRA4 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs760985980, COSV60327251, COSV60328111; called by muse, mutect2, varscan2
- IGLL5 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as COSV101138966, COSV66536088; called by muse, mutect2, varscan2
- KLF6 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51494828, COSV99435296; called by muse, mutect2, varscan2
- LRRC6 | c.842A>G p.K281R | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.157); catalogued as COSV99138556; called by muse, mutect2
- LRRK2 | c.5192G>C p.R1731T | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.518); catalogued as COSV100110279, COSV100111099; called by muse, mutect2, varscan2
- MAP7D1 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV100294798; called by muse, mutect2, varscan2
- MPP1 | c.481-1G>C p.X161_splice | Splice Site (SNP) | VAF 17/281 reads (6%) | catalogued as COSV101053752; called by muse, mutect2
- MYBBP1A | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs746267976, COSV99626899; called by muse, mutect2, varscan2
- MYH1 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.099); catalogued as COSV99820919; called by muse, mutect2, varscan2
- NAV3 | c.4205G>C p.R1402T | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99895364; called by muse, mutect2, varscan2
- NPRL3 | c.1364A>T p.D455V (on ENST00000611875 / NM_001077350.3; = p.D430V on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99550067; called by muse, mutect2, varscan2
- OAS2 | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100660313; called by muse, mutect2, varscan2
- PHYHD1 | c.629C>T p.A210V (on ENST00000372592 / NM_001100876.2; = p.R203C on NM_174933.4) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs556760788, COSV100455272; called by muse, mutect2, varscan2
- PLEKHN1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.729); catalogued as rs765403798, COSV100379293; called by muse, mutect2, varscan2
- PLXNA4 | c.5584G>A p.E1862K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs771291757, COSV58109809; called by muse, mutect2, varscan2
- POU4F1 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101020598; called by muse, mutect2
- RFX7 | c.91G>T p.E31* (on ENST00000559447 / NM_001368074.1; = p.E128* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100429364; called by muse, mutect2, varscan2
- SGSM3 | c.1458G>T p.K486N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1304692315, COSV99960658; called by muse, mutect2, varscan2
- SSH3 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs775533885, COSV57384525; called by muse, mutect2, varscan2
- TMEM98 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.35); catalogued as COSV99912924; called by muse, mutect2, varscan2
- WDCP | c.1853G>C p.R618T | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99722216; called by muse, mutect2, varscan2
- ZSWIM7 | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.184); catalogued as COSV101233782; called by muse, mutect2, varscan2
- GLIPR1L1 | c.193_195del p.A65del | In Frame Del (DEL) | VAF 13/138 reads (9%) | called by mutect2, pindel
- AHR | c.468G>A p.Q156= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as COSV54124652, COSV99620223; called by muse, mutect2, varscan2
- BACH2 | c.1593C>T p.D531= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs201225316, COSV57585469, COSV57591025; called by muse, mutect2, varscan2
- BDP1 | c.2991T>C p.N997= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV100703497; called by muse, mutect2, varscan2
- CLEC16A | c.1503G>T p.V501= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs753860301, COSV101278453, COSV68498804; called by muse, varscan2
- CWH43 | c.624C>T p.L208= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs775869448, COSV99892533, COSV99894084; called by muse, mutect2, varscan2
- DLG3 | c.1626G>A p.E542= (on ENST00000374360 / NM_021120.4; = p.E205= on NM_020730.3) | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99530082; called by mutect2, varscan2
- ELAPOR1 | c.2280C>T p.V760= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100884402; called by muse, mutect2, varscan2
- PAPPA2 | c.169C>A p.R57= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100867139, COSV62772170; called by muse, mutect2, varscan2
- PTPRH | c.2283C>T p.G761= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99671432; called by muse, mutect2, varscan2
- PTPRN2 | c.1518C>T p.S506= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs755213854, COSV67036845; called by muse, mutect2, varscan2
- RTN3 | c.2898G>C p.L966= (on ENST00000377819 / NM_001265589.2; = p.L170= on NM_006054.4) | Silent (SNP) | VAF 71/212 reads (33%) | catalogued as COSV100380335; called by muse, mutect2, varscan2
- SH2D3A | c.231C>T p.L77= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs1173143827, COSV99838099; called by muse, mutect2, varscan2
- KYNU | c.902+2836C>T | Intron (SNP) | VAF 24/61 reads (39%) | catalogued as COSV51579004, COSV51581929, COSV99933990; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 15/29 reads (52%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
- TIMM50 | chr19:39480737 G>C | 5'Flank (SNP) | VAF 6/27 reads (22%) | catalogued as rs778353895, COSV100068083; called by muse, varscan2
